Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5168, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5168-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

TCGA-BP-5168

Clinical Diagnosis & History:

Right renal mass.

Specimens Submitted:

1: SP: Right renal tumor

2: SP: Deep margin #2

3: SP: Right renal cyst wall

4: SP: Paracaval node tissue

DIAGNOSIS:

- 1) KIDNEY, RIGHT; PARTIAL NEPHRECTOMY:
- RENAL CELL CARCINOMA, CONVENTIONAL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS SOLID.
- THE TUMOR'S GREATEST DIAMETER IS 4.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- 2) DEEP MARGIN #2; BIOPSY
- BENIGN RENAL PARENCHYMA.
- 3) KIDNEY, RIGHT, CYST WALL; EXCISION:
- BENIGN SIMPLE CYST.
- 4) PARACAVAL LYMPH NODE; BIOPSY:
- BENIGN FIBROCONNECTIVE TISSUE.
- NO LYMPH NODE IDENTIFIED AFTER EXAMINING THE ENTIRELY SUBMITTED SPECIMEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

- 1) The specimen is received fresh for frozen section, labeled "Right Renal Tumor (stitch marks deep margin)". It consists of a portion of kidney measuring 4.5 x 4.5 x 4 cm. The surgical margin is inked black. The renal capsule and perirenal fat are inked in blue. On cut surface, a well-circumscribed, partially cystic mass with intermixed yellow and golden color consistent with necrosis, is identified. The mass measure 4 x 4 x 4 cm in greatest dimensions. It is abutting the renal capsule and focally approaching the black surgical margin as well. The tumor does not appear to penetrate through the capsule.

Summary of Sections:

FSC - frozen section control

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

CAP – capsule
T – tumor
M – surgical margins

2) The specimen is received fresh for frozen section, labeled "Deep Margin #2". It consists of a piece of soft tissue, entirely submitted for frozen section.

Summary of Sections:
FSC - frozen section control

3) The specimen is received in formalin, labeled "Right Renal Cyst Wall". It consists of a small piece of tan, soft tissue measuring 0.3 x 0.3 x 0.3 cm. Entirely submitted.

Summary of Sections:
U - undesignated

4) The specimen is received in formalin, labeled "Paracaval Node Tissue". It consists of multiple fragments of adipose tissue measuring 5 x 5 x 0.3 cm. Careful inspection did not reveal lymph nodes. Entirely submitted.

Summary of Sections:
U - undesignated

Summary of Sections:

Part 1: SP: Right renal tumor

Block	Sect. Site	PCs
1	cap	1
1	fsc	1
1	m	1
2	t	2

Part 2: SP: Deep margin #2

Block	Sect. Site	PCs
1	fsc	1

Part 3: SP: Right renal cyst wall

Block	Sect. Site	PCs
1	u	1

Part 4: SP: Paracaval node tissue

Block	Sect. Site	PCs
2	u	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM CLEAR CELL TYPE. MARGIN CLEAR.

[page 3 of 3]
[REDACTED] [REDACTED]
SURGICAL PATHOLOGY REPORT

2) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL NEOPLASM CLEAR CELL TYPE. MARGIN CLEAR. [REDACTED]
[REDACTED] [REDACTED]
[REDACTED]

Source: NCI Genomic Data Commons file c7e00616-4c09-4c7f-be72-c0d881fcd884 (TCGA-BP-5168.F1FAE1D5-BA38-49C4-A66E-F977CA7D5E3B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).